Somatic mutation profile of tumor specimen HCM-BROD-0011-C71-01A (aliquot HCM-BROD-0011-C71-01A-01D-A768-36) from HCMI case HCM-BROD-0011-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.7 years (19,996 days).
Specimen HCM-BROD-0011-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 741293c5-f222-423f-8e97-e8d680b4f7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0011-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0011-C71-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8c59308-850c-4169-b014-1d9e9befed40

The open-access MAF lists 32 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, RNA 3, Intron 3, Nonsense Mutation 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1746-1G>C p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 71/236 reads (30%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- SMC1A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 147/254 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs587784422, COSV59132231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMC5 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767369427, COSV51659395; called by muse, mutect2, varscan2
- NGFR | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 94/339 reads (28%) | catalogued as rs757264010; called by muse, mutect2, varscan2
- PAPPA2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755342431, COSV62774296, COSV62782315; called by muse, mutect2
- SAA2-SAA4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs565392562, COSV53447756; called by muse, mutect2, varscan2
- SLC6A6 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1471241843, COSV62649040; called by muse, mutect2, varscan2
- UBQLN3 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148446760; called by muse, mutect2, varscan2
- BHMT | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CDH15 | c.1792G>C p.G598R | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DLX5 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 20/429 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- MMP24 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NCAM2 | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- P2RY2 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.8935C>T p.R2979C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVEP1 | c.9338C>T p.P3113L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AOX1 | c.3204G>A p.S1068= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs745437388, COSV53497005; called by muse, mutect2, varscan2
- CNTNAP2 | c.429C>T p.D143= | Silent (SNP) | VAF 109/610 reads (18%) | catalogued as rs866657669; called by muse, mutect2, varscan2
- GREB1L | c.2424T>C p.I808= | Silent (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- KRTAP10-3 | c.327C>T p.C109= | Silent (SNP) | VAF 289/971 reads (30%) | called by muse, mutect2, varscan2
- LILRA1 | c.879C>T p.G293= | Silent (SNP) | VAF 142/781 reads (18%) | catalogued as COSV52179467; called by muse, mutect2, varscan2
- MMEL1 | c.798C>T p.N266= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs576993818; called by muse, mutect2, varscan2
- PTPRB | c.786T>C p.P262= | Silent (SNP) | VAF 74/299 reads (25%) | called by muse, mutect2, varscan2
- SLC13A4 | c.150G>A p.S50= | Silent (SNP) | VAF 65/484 reads (13%) | catalogued as rs150811537; called by muse, mutect2, varscan2
- UTS2R | c.120C>T p.T40= | Silent (SNP) | VAF 70/309 reads (23%) | catalogued as rs377274020, COSV57453005; called by muse, mutect2, varscan2
- AC024940.1 | n.4294C>A | RNA (SNP) | VAF 40/193 reads (21%) | called by muse, mutect2, varscan2
- BDH1 | c.562+14G>A | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- DAZAP1 | c.30-42G>T | Intron (SNP) | VAF 91/314 reads (29%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2357A>G | 3'UTR (SNP) | VAF 57/333 reads (17%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.423G>T | RNA (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- MYADML | n.1174T>C | RNA (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- ZNF789 | c.265+1100A>G | Intron (SNP) | VAF 54/314 reads (17%) | catalogued as rs1166346081; called by muse, mutect2, varscan2
